Somatic mutation profile of tumor specimen TCGA-CV-7095-01A (aliquot TCGA-CV-7095-01A-21D-2012-08) from TCGA case TCGA-CV-7095, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 87.7 years (32,022 days).
Specimen TCGA-CV-7095-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64cbbdba-fa00-4e4d-b612-57a34a2d3061.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7095-10A (Blood Derived Normal), aliquot TCGA-CV-7095-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd7cf1da-0d2b-4256-9d48-09cd29fc1380

The open-access MAF lists 260 somatic variants for this specimen: 193 protein-altering or splice-affecting, 62 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 167, Silent 62, Nonsense Mutation 18, Intron 4, Frame Shift Del 3, Splice Site 3, Frame Shift Ins 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.4090G>C p.V1364L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as COSV100217572, COSV100217706; called by muse, mutect2, varscan2
- AC139530.2 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs368964351; called by muse, mutect2, varscan2
- ACACB | c.4408G>C p.E1470Q | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.986); catalogued as COSV100623274, COSV58127638; called by muse, mutect2, varscan2
- ACVR1C | c.1405G>A p.G469R | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54644304; called by muse, mutect2, varscan2
- ADA2 | c.1418A>T p.K473I (on ENST00000262607; = p.K232I on NM_177405.3) | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99376441; called by muse, mutect2, varscan2
- ADAMTS7 | c.1786C>T p.R596C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.517); catalogued as rs751603055, COSV101183242, COSV66308080; called by muse, mutect2, varscan2
- AGPAT1 | c.554G>C p.G185A | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100421707; called by muse, mutect2, varscan2
- AGTPBP1 | c.84C>G p.I28M | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as rs763266030, COSV100430227; called by muse, mutect2, varscan2
- ALLC | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.088); catalogued as rs1168305633, COSV52993269; called by muse, mutect2, varscan2
- ANOS1 | c.1347G>C p.K449N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.092); catalogued as COSV99391386; called by muse, mutect2
- AP3B2 | c.1739G>A p.R580H | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866031332, COSV99916989; called by muse, mutect2, varscan2
- APBB1 | c.698C>G p.S233C | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV100194305; called by muse, mutect2, varscan2
- ASPA | c.414G>C p.Q138H | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (1); PolyPhen possibly damaging (0.485); catalogued as COSV99559324; called by muse, mutect2
- ASTE1 | c.21G>C p.M7I | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); catalogued as COSV99393985; called by muse, mutect2, varscan2
- BAIAP2L1 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99134812; called by muse, varscan2
- BDNF | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.752); catalogued as COSV59238851; called by muse, mutect2, varscan2
- BFSP1 | c.1183G>C p.E395Q | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV100925456; called by muse, mutect2, varscan2
- BIRC6 | c.8621C>G p.S2874* | Nonsense Mutation (SNP) | VAF 48/178 reads (27%) | catalogued as COSV101428832; called by muse, mutect2, varscan2
- BPIFB2 | c.856-1G>A p.X286_splice | Splice Site (SNP) | VAF 46/135 reads (34%) | catalogued as rs773937575, COSV99401664; called by muse, mutect2, varscan2
- BRWD3 | c.1486G>A p.D496N | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV100956507; called by muse, mutect2, varscan2
- C4orf33 | c.96G>A p.M32I | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV99829041; called by muse, mutect2, varscan2
- C6 | c.2639G>C p.C880S | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54709625; called by muse, mutect2, varscan2
- CACNA1D | c.2032T>A p.F678I (on ENST00000350061 / NM_001128840.3; = p.F698I on NM_000720.4) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV99859941; called by muse, mutect2, varscan2
- CASP8 | c.908A>T p.D303V (on ENST00000432109 / NM_033355.3; = p.D320V on NM_001228.4) | Missense Mutation (SNP) | VAF 84/170 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV99629570, COSV99630812; called by muse, mutect2, varscan2
- CBLL1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 62/200 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.503); catalogued as COSV99755911; called by muse, mutect2, varscan2
- CCDC93 | c.260C>G p.S87* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as COSV100099429; called by muse, mutect2, varscan2
- CCSER1 | c.655A>G p.R219G | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as COSV100395884; called by muse, mutect2, varscan2
- CD19 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV100218255; called by muse, mutect2, varscan2
- CEBPG | c.277A>T p.R93* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as COSV99392865; called by muse, mutect2, varscan2
- CEP350 | c.2518G>C p.E840Q | Missense Mutation (SNP) | VAF 60/235 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100855197; called by muse, mutect2, varscan2
- CERS6 | c.385C>G p.L129V | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.515); catalogued as COSV99987708; called by muse, mutect2, varscan2
- CFAP52 | c.1640C>G p.S547W | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs756886009, COSV99557034; called by muse, mutect2, varscan2
- CFP | c.625T>C p.C209R | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99901658; called by muse, mutect2, varscan2
- CKLF | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV50451603, COSV99862687; called by muse, mutect2, varscan2
- CNTNAP2 | c.1999G>A p.A667T | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as rs374920791; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COCH | c.631G>C p.G211R (on ENST00000216361 / NM_001347720.1; = p.G146R on NM_004086.3) | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV99363913; called by muse, mutect2, varscan2
- COG5 | c.46C>G p.R16G | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as COSV51764854; called by muse, mutect2, varscan2
- COL3A1 | c.2279C>G p.P760R | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.118); catalogued as COSV100483682; called by muse, mutect2
- COLEC12 | c.1413G>T p.E471D | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.88); PolyPhen benign (0.028); catalogued as COSV101232161; called by muse, mutect2, varscan2
- COLGALT2 | c.776A>C p.D259A | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100730857; called by muse, mutect2, varscan2
- CPA6 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775233588, COSV52721227; called by muse, mutect2, varscan2
- CPSF7 | c.161C>G p.P54R (on ENST00000394888 / NM_001136040.4; = p.P97R on NM_024811.4) | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as rs1199842499, COSV100467582; called by muse, mutect2, varscan2
- CTTNBP2 | c.1231C>G p.Q411E | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.034); catalogued as rs1469072783, COSV50404392, COSV99354801; called by muse, mutect2, varscan2
- CXXC1 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs769478251, COSV53273975; called by muse, mutect2
- CYP2W1 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.84); PolyPhen benign (0.017); catalogued as COSV100417315; called by muse, mutect2, varscan2
- DCAF17 | c.719C>A p.T240N | Missense Mutation (SNP) | VAF 82/322 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.022); catalogued as COSV100266380; called by muse, mutect2, varscan2
- DENND2B | c.1924G>A p.E642K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100567822; called by muse, mutect2
- DLK1 | c.1113G>A p.M371I | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV100375441; called by muse, mutect2, varscan2
- DMD | c.6521C>G p.S2174* | Nonsense Mutation (SNP) | VAF 22/98 reads (22%) | catalogued as COSV100629180; called by muse, mutect2, varscan2
- DNAH3 | c.8348C>T p.S2783L | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as rs1026628452, COSV54554084; called by muse, mutect2, varscan2
- DOK6 | c.434C>G p.P145R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101234972; called by muse, mutect2, varscan2
- DTX1 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.338); catalogued as rs200220437, COSV57501747; called by muse, mutect2, varscan2
- DUS3L | c.1681T>A p.W561R | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100288456; called by muse, mutect2, varscan2
- DYNC1LI2 | c.818C>G p.S273* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as COSV99263251; called by muse, mutect2, varscan2
- ECE2 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs780163260, COSV100668835; called by muse, varscan2
- ELAVL4 | c.83A>G p.N28S | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100836885; called by muse, mutect2, varscan2
- ELP4 | c.142T>C p.S48P | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.495); catalogued as COSV99541308; called by muse, mutect2, varscan2
- EP300 | c.5313C>A p.C1771* | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as COSV99067021; called by muse, mutect2, varscan2
- EPHA5 | c.1084C>G p.R362G | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV99901100; called by muse, mutect2, varscan2
- EPHB6 | c.2201G>A p.R734Q | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs201556658, COSV63892635; called by muse, mutect2, varscan2
- EYS | c.388C>A p.L130I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.236); catalogued as COSV100677132; called by muse, mutect2, varscan2
- F13B | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs192220037, COSV66374039; called by muse, mutect2, varscan2
- FAM135B | c.371T>G p.L124W | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99358091; called by muse, mutect2, varscan2
- FAT1 | c.8488C>T p.Q2830* | Nonsense Mutation (SNP) | VAF 38/112 reads (34%) | catalogued as COSV71673183; called by muse, mutect2, varscan2
- FBXW7 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.454); catalogued as rs751626529, COSV55929418; called by muse, mutect2, varscan2
- FLG | c.7508C>T p.A2503V | Missense Mutation (SNP) | VAF 191/558 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as rs780063414, COSV100911868; called by muse, mutect2, varscan2
- FOLH1 | c.13C>T p.L5F | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.771); catalogued as rs953040896, COSV99923884; called by muse, mutect2
- FREM1 | c.1246G>T p.V416L | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100772225; called by muse, mutect2, varscan2
- GDF3 | c.747G>C p.R249S | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100325390, COSV61711898; called by muse, mutect2, varscan2
- GLIS3 | c.1271C>T p.S424L | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100173136, COSV100174787; called by muse, mutect2, varscan2
- GRIN2A | c.4274C>G p.S1425W | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV100410975, COSV58018897; called by muse, mutect2, varscan2
- GYG1 | c.109G>A p.V37M | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as rs913039791, COSV99936953, COSV99937001; called by muse, mutect2, varscan2
- HSD3B1 | c.934C>T p.R312* | Nonsense Mutation (SNP) | VAF 42/173 reads (24%) | catalogued as COSV52491370; called by muse, mutect2, varscan2
- IDUA | c.680C>G p.T227S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV99926431; called by muse, mutect2
- IRF2BP2 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 5/12 reads (42%) | catalogued as COSV100784403; called by muse, mutect2, varscan2
- IRX1 | c.1229C>G p.P410R | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.116); catalogued as COSV100116791, COSV57359018; called by muse, mutect2, varscan2
- ITGA2 | c.824C>T p.T275M | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs753108742, COSV99671563; called by muse, mutect2, varscan2
- KCNH8 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60477857, COSV60480152; called by muse, mutect2
- KCNU1 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.26); catalogued as COSV101299420; called by muse, mutect2, varscan2
- KCTD13 | c.883G>A p.G295R | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.616); catalogued as rs746822848, COSV100441845; called by muse, mutect2, varscan2
- KCTD2 | c.461A>T p.E154V | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100483337, COSV100483381; called by muse, mutect2, varscan2
- KIF1B | c.2558G>A p.R853Q (on ENST00000377086 / NM_001365952.1; = p.R807Q on NM_015074.3) | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs752039135, COSV55804929; called by muse, mutect2, varscan2
- KIF26B | c.1721C>G p.S574C | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100833373; called by muse, mutect2, varscan2
- KL | c.325C>G p.L109V | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV101199195; called by muse, mutect2
- LAMA2 | c.3460G>A p.G1154R | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756475916, COSV70348110; called by muse, mutect2, varscan2
- LAMA4 | c.2490C>G p.S830R (on ENST00000230538 / NM_001105206.3; = p.S823R on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.771); catalogued as COSV100039389; called by muse, mutect2, varscan2
- LDHC | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as rs777146300, COSV55003283; called by muse, mutect2, varscan2
- LEPR | c.2686G>C p.E896Q | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV100848419; called by muse, mutect2, varscan2
- LIMS2 | c.176A>G p.E59G (on ENST00000355119 / NM_001161403.3; = p.E83G on NM_017980.4) | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99760759; called by muse, mutect2
- LIPE | c.1546T>C p.F516L | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV99734395; called by muse, mutect2, varscan2
- MADD | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.425); catalogued as COSV100211942; called by muse, mutect2, varscan2
- MAP1A | c.7109del p.P2370Qfs*84 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | catalogued as rs1315632524, COSV100288705; called by mutect2, pindel, varscan2
- MAPK8IP3 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747806738, COSV51717417; called by muse, mutect2, varscan2
- MARCHF4 | c.1042G>T p.E348* | Nonsense Mutation (SNP) | VAF 19/47 reads (40%) | catalogued as COSV99814770; called by muse, mutect2, varscan2
- ME2 | c.862C>G p.L288V | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV100360933; called by muse, mutect2, varscan2
- MGAT3 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV100362061; called by muse, mutect2
- MNT | c.373G>A p.G125S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1294099040, COSV99438266; called by muse, mutect2
- MRTFA | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1295279056, COSV62932348; called by muse, mutect2, varscan2
- MXRA5 | c.2045G>A p.R682H | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs745871213, COSV54224205; called by muse, mutect2, varscan2
- MYH11 | c.3058G>A p.E1020K | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV100260207; called by muse, mutect2, varscan2
- MYLK3 | c.2401-1G>A p.X801_splice | Splice Site (SNP) | VAF 14/70 reads (20%) | catalogued as rs868721921, COSV101189205; called by muse, mutect2, varscan2
- NCAPD3 | c.1531T>C p.S511P | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV101599401; called by muse, mutect2, varscan2
- NDN | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.08); catalogued as rs910356078, COSV100086712; called by muse, mutect2, varscan2
- NIPBL | c.6664G>C p.D2222H | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV56972328; called by muse, mutect2, varscan2
- NKAIN4 | c.571C>T p.H191Y | Missense Mutation (SNP) | VAF 68/279 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99416987; called by muse, mutect2, varscan2
- NOTCH3 | c.5678G>A p.R1893Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372834264; ClinVar: benign; called by muse, mutect2
- NRG3 | c.2009G>T p.R670L (on ENST00000404547 / NM_001370084.1; = p.R646L on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as rs150401464, COSV100932179; called by muse, mutect2, varscan2
- NUTM1 | c.2875G>T p.G959W | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.841); catalogued as COSV100149064; called by muse, mutect2, varscan2
- OBSCN | c.12482T>C p.I4161T | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99483991; called by muse, mutect2, varscan2
- OR10R2 | c.677T>C p.V226A | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.232); catalogued as rs772048262, COSV100936841; called by muse, mutect2, varscan2
- OR11H12 | c.538C>G p.Q180E | Missense Mutation (SNP) | VAF 28/402 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV101612531, COSV73569045; called by muse, mutect2
- OR14J1 | c.514A>G p.I172V | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.133); catalogued as COSV101012856; called by muse, mutect2, varscan2
- OR9A4 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs1379052061, COSV71886052; called by muse, mutect2, varscan2
- OSBPL2 | c.73G>A p.E25K (on ENST00000313733 / NM_144498.4; = p.X13_splice on NM_014835.4) | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.269); catalogued as COSV100569340; called by muse, mutect2, varscan2
- OTOP1 | c.1333G>C p.E445Q | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99588054; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.778G>C p.E260Q (on ENST00000259318 / NM_001136562.3; = p.E491Q on NM_007203.5) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99395709; called by muse, mutect2, varscan2
- PAPPA2 | c.1703G>A p.S568N | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV62772479; called by muse, mutect2, varscan2
- PARP14 | c.2963C>T p.P988L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs771490414, COSV71735627; called by muse, mutect2
- PFKP | c.2224G>C p.E742Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV99829571; called by mutect2, varscan2
- PHIP | c.4477C>G p.Q1493E | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.344); catalogued as COSV99244855; called by muse, mutect2
- PITPNM1 | c.1085A>G p.E362G | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV100711731; called by muse, mutect2
- PLCE1 | c.634G>T p.D212Y | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as rs776583769, COSV53336645, COSV99597033; called by muse, mutect2, varscan2
- PLCE1 | c.981G>C p.R327S | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99597038; called by muse, varscan2
- PLCZ1 | c.85G>C p.E29Q | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.796); catalogued as COSV56859537, COSV99856951; called by muse, mutect2, varscan2
- PLEKHA2 | c.707G>T p.R236L | Missense Mutation (SNP) | VAF 95/336 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as rs762621728, COSV66242396; called by muse, mutect2, varscan2
- PLXNA1 | c.2429C>T p.P810L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.109); catalogued as rs1475759518, COSV52527828; called by mutect2, varscan2
- POLR1A | c.3658G>A p.G1220R | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1461382886, COSV55691353; called by muse, mutect2, varscan2
- PPP1R1A | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99226523; called by muse, mutect2, varscan2
- PRR5L | c.692C>G p.S231* | Nonsense Mutation (SNP) | VAF 14/53 reads (26%) | catalogued as COSV100287367; called by muse, mutect2, varscan2
- PUS7 | c.1885C>G p.L629V | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100708644; called by muse, mutect2, varscan2
- PYGM | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV51230021, COSV99377591; called by muse, mutect2, varscan2
- RABGAP1 | c.2782A>T p.K928* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as rs1564193686, COSV101017169; called by muse, mutect2, varscan2
- RADIL | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs774854763, COSV68200117; called by muse, mutect2, varscan2
- RANBP3L | c.296C>G p.S99* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as COSV56954294; called by muse, mutect2
- RBM34 | c.1051G>C p.E351Q | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.356); catalogued as COSV100784055; called by muse, mutect2, varscan2
- RGP1 | c.205C>A p.Q69K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100960351; called by mutect2, varscan2
- ROCK2 | c.412del p.W138Gfs*31 | Frame Shift Del (DEL) | VAF 31/145 reads (21%) | catalogued as rs755738345; called by mutect2, pindel, varscan2
- ROPN1B | c.230C>G p.S77C | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs780039344, COSV99305680; called by muse, mutect2, varscan2
- SACS | c.4967T>G p.V1656G | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV101207712; called by muse, mutect2, varscan2
- SCAF4 | c.2260C>T p.P754S | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.628); catalogued as COSV99742114; called by muse, mutect2, varscan2
- SEMA3E | c.1049G>T p.R350L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100319552, COSV57094204; called by muse, mutect2, varscan2
- SENP1 | c.389C>G p.S130* | Nonsense Mutation (SNP) | VAF 11/51 reads (22%) | catalogued as COSV99137172; called by muse, mutect2, varscan2
- SHPRH | c.3317A>T p.Y1106F (on ENST00000275233 / NM_001042683.3; = p.Y1115F on NM_173082.3) | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99262652; called by muse, mutect2, varscan2
- SIGLEC1 | c.5098G>A p.E1700K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.051); catalogued as COSV99170716; called by muse, mutect2, varscan2
- SIPA1L1 | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.444); catalogued as COSV100666036; called by muse, mutect2, varscan2
- SIPA1L3 | c.1907C>G p.S636C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV99730357; called by muse, mutect2, varscan2
- SIX6 | c.565A>T p.K189* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV100576545; called by muse, mutect2
- SLC12A4 | c.3011G>C p.R1004P | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs768693498, COSV99863292; called by muse, mutect2, varscan2
- SLC2A14 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.159); catalogued as rs747572869, COSV100534014; called by mutect2, varscan2
- SLC2A3 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.077); catalogued as rs769142515, COSV99306922; called by muse, mutect2, varscan2
- SLC5A7 | c.206A>G p.N69S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as COSV99887209; called by muse, mutect2, varscan2
- SNCAIP | c.1057C>G p.L353V | Missense Mutation (SNP) | VAF 59/115 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99750275; called by muse, mutect2, varscan2
- SPEM2 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 34/209 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as COSV100081264; called by muse, mutect2, varscan2
- SPEM2 | c.1436C>T p.S479L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs200505211, COSV100424491; called by muse, mutect2, varscan2
- SPTBN2 | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.053); catalogued as rs749463565, COSV100020426; called by muse, mutect2, varscan2
- SSH3 | c.1645G>T p.E549* | Nonsense Mutation (SNP) | VAF 14/222 reads (6%) | catalogued as COSV100354794; called by muse, mutect2
- STXBP2 | c.1049C>G p.A350G | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99657382; called by muse, mutect2
- SYNE1 | c.3907G>A p.E1303K (on ENST00000367255 / NM_182961.4; = p.E1310K on NM_033071.3) | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV99577608; called by muse, mutect2, varscan2
- TANC1 | c.4183G>A p.E1395K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99715118; called by muse, mutect2, varscan2
- TAS2R16 | c.473A>G p.E158G | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV50799609, COSV99972348; called by muse, mutect2, varscan2
- TAS2R20 | c.113G>A p.R38K | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.173); catalogued as rs1430631422, COSV101115564; called by muse, mutect2, varscan2
- TCIRG1 | c.1690C>T p.H564Y | Missense Mutation (SNP) | VAF 24/291 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.013); catalogued as COSV99693612; called by muse, mutect2
- TCN1 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 46/209 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.009); catalogued as rs200856109, COSV99074672, COSV99953447; called by muse, mutect2, varscan2
- TMCC3 | c.971A>T p.Q324L | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV99705668; called by muse, varscan2
- TPSD1 | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs755611201, COSV52974574, COSV99274190; called by muse, varscan2
- TRIM26 | c.939G>A p.V313= | Splice Region (SNP) | VAF 15/60 reads (25%) | catalogued as COSV101443974; called by muse, mutect2, varscan2
- TRIO | c.4808A>G p.E1603G | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100710933; called by muse, mutect2, varscan2
- TRIP11 | c.4985C>T p.S1662F | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV99971155; called by muse, mutect2, varscan2
- TRMU | c.995G>C p.R332P | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99324696; called by muse, mutect2, varscan2
- TRMU | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV99324699; called by muse, mutect2, varscan2
- TTN | c.46371G>A p.M15457I (on ENST00000591111; = p.M8033I on NM_003319.4) | Missense Mutation (SNP) | VAF 151/333 reads (45%) | PolyPhen probably damaging (0.961); catalogued as COSV100628798; called by muse, mutect2, varscan2
- TUBB4A | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as rs748510977, COSV51152147; called by muse, mutect2, varscan2
- UNC13B | c.2718+2T>C p.X906_splice | Splice Site (SNP) | VAF 29/136 reads (21%) | catalogued as COSV101037268; called by muse, mutect2, varscan2
- UNC13C | c.6294G>T p.K2098N | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.658); catalogued as COSV99522730; called by muse, mutect2, varscan2
- UNC5D | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 62/129 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.041); catalogued as rs190579280, COSV99779975; called by muse, mutect2, varscan2
- USP8 | c.1708G>C p.D570H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV100209273; called by muse, mutect2, varscan2
- WSB1 | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 38/255 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV99286151; called by muse, mutect2, varscan2
- XRCC6 | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV100777915; called by muse, mutect2
- YWHAE | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.005); catalogued as rs11552915, COSV99981555; called by muse, mutect2, varscan2
- ZNF28 | c.1978G>C p.E660Q | Missense Mutation (SNP) | VAF 26/261 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.569); catalogued as COSV100354718; called by muse, mutect2, varscan2
- ZNF300 | c.356G>A p.G119D | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753958498, COSV99200155; called by muse, mutect2, varscan2
- ZNF415 | c.984C>A p.Y328* | Nonsense Mutation (SNP) | VAF 39/80 reads (49%) | catalogued as COSV99702000; called by muse, mutect2, varscan2
- ZNF443 | c.1666G>A p.G556R | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV100042021; called by muse, mutect2, varscan2
- ZNF449 | c.1481C>T p.T494I | Missense Mutation (SNP) | VAF 101/245 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.211); catalogued as COSV100203063; called by muse, mutect2, varscan2
- ZNF521 | c.1539C>G p.F513L | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as rs758175472, COSV100833332, COSV64123101; called by muse, mutect2, varscan2
- ZNF622 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 68/162 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV58075698; called by muse, mutect2, varscan2
- ZNF630 | c.1686G>C p.Q562H | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.858); catalogued as COSV99332584; called by muse, mutect2, varscan2
- ZNF711 | c.995G>C p.R332T | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as rs1216545696, COSV52155143, COSV99341574; called by muse, mutect2, varscan2
- ZNF79 | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100688251; called by muse, mutect2, varscan2
- AC131160.1 | c.990del p.F330Lfs*23 | Frame Shift Del (DEL) | VAF 23/84 reads (27%) | called by mutect2, pindel, varscan2
- PLEKHA6 | c.2508G>A p.M836I | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- PMS1 | c.294dup p.S99Vfs*7 | Frame Shift Ins (INS) | VAF 33/114 reads (29%) | called by mutect2, pindel, varscan2
- ACBD6 | c.129C>T p.A43= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV62573140; called by muse, mutect2, varscan2
- AMBP | c.786C>T p.G262= | Silent (SNP) | VAF 25/114 reads (22%) | catalogued as rs374833274; called by muse, mutect2, varscan2
- C7orf33 | c.24C>G p.L8= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as COSV100188919; called by muse, mutect2, varscan2
- CANT1 | c.780G>A p.E260= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100185378; called by muse, mutect2, varscan2
- CCDC33 | c.351G>A p.K117= | Silent (SNP) | VAF 32/152 reads (21%) | catalogued as COSV100351837; called by muse, mutect2, varscan2
- CMTR1 | c.204C>T p.D68= | Silent (SNP) | VAF 42/96 reads (44%) | catalogued as rs905813720, COSV65089974; called by muse, mutect2, varscan2
- CNTN2 | c.2349C>A p.P783= | Silent (SNP) | VAF 23/111 reads (21%) | catalogued as COSV100085441; called by muse, mutect2, varscan2
- COL14A1 | c.3450G>C p.V1150= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV99920584; called by muse, mutect2, varscan2
- CREBBP | c.7281C>T p.V2427= | Silent (SNP) | VAF 40/186 reads (22%) | catalogued as rs764396354, COSV52136742; called by muse, mutect2, varscan2
- DCAF15 | c.1212G>A p.P404= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as rs763384916, COSV54328284; called by muse, mutect2, varscan2
- DGKQ | c.1593C>T p.S531= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs752716017, COSV56617499; called by muse, mutect2
- DNAH2 | c.7512C>T p.L2504= | Silent (SNP) | VAF 23/119 reads (19%) | catalogued as COSV101209579, COSV66717645; called by muse, mutect2, varscan2
- FGGY | c.459G>C p.L153= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100365856; called by muse, mutect2, varscan2
- FLT4 | c.2460G>T p.G820= | Silent (SNP) | VAF 54/105 reads (51%) | catalogued as COSV99988871, COSV99989517; called by muse, mutect2, varscan2
- FRAS1 | c.8493C>T p.F2831= | Silent (SNP) | VAF 69/264 reads (26%) | catalogued as rs774409872, COSV53627676; called by muse, mutect2, varscan2
- GRIP1 | c.87G>A p.Q29= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as rs1049563945, COSV99670917; called by muse, mutect2, varscan2
- HLA-G | c.396C>T p.R132= | Silent (SNP) | VAF 27/118 reads (23%) | catalogued as rs765636576, COSV100827190; called by muse, mutect2, varscan2
- KDM7A | c.2241C>T p.S747= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV99135110; called by muse, mutect2, varscan2
- LMTK2 | c.4158G>A p.P1386= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs146973469; called by muse, varscan2
- LONRF2 | c.1263G>A p.K421= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as rs1329828868, COSV101111053; called by muse, mutect2, varscan2
- LRP1 | c.549G>A p.P183= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs990497481, COSV99677127; called by muse, mutect2, varscan2
- MAGEC1 | c.2283G>A p.E761= | Silent (SNP) | VAF 84/340 reads (25%) | catalogued as rs757645761, COSV99596458; called by muse, mutect2, varscan2
- MAP1LC3B2 | c.60C>G p.V20= | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as rs1316383402, COSV100186670; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1830C>G p.V610= | Silent (SNP) | VAF 28/115 reads (24%) | catalogued as COSV99571760; called by muse, mutect2, varscan2
- MCM3AP | c.1755C>T p.L585= | Silent (SNP) | VAF 14/129 reads (11%) | catalogued as rs771124524, COSV52437243; called by muse, mutect2, varscan2
- METTL21C | c.681C>T p.F227= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV99940141; called by muse, mutect2, varscan2
- MSI1 | c.594G>T p.G198= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as rs757303115, COSV99981708; called by muse, mutect2, varscan2
- MYH3 | c.1329C>T p.R443= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as COSV99878831; called by muse, mutect2, varscan2
- MYOCD | c.696A>T p.I232= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as rs370115389; called by muse, mutect2, varscan2
- NEDD4 | c.1167C>T p.D389= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV100164086; called by muse, mutect2, varscan2
- NIN | c.3463C>T p.L1155= | Silent (SNP) | VAF 24/241 reads (10%) | catalogued as COSV99815149; called by muse, mutect2, varscan2
- ONECUT2 | c.1461C>T p.D487= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as rs765657446, COSV72153039; called by muse, mutect2, varscan2
- PCDHB2 | c.2086T>C p.L696= | Silent (SNP) | VAF 69/288 reads (24%) | catalogued as rs782414360, COSV50618660, COSV99166550; called by muse, mutect2, varscan2
- PCDHB3 | c.2080T>C p.L694= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as COSV99166558; called by muse, mutect2, varscan2
- PCLO | c.10725A>T p.T3575= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV100437470; called by muse, mutect2, varscan2
- PLCE1 | c.216T>C p.I72= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV99597030; called by muse, mutect2, varscan2
- PLEC | c.6216G>A p.E2072= (on ENST00000322810 / NM_201380.4; = p.E1962= on NM_000445.5) | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs1554695859, COSV100518655; called by muse, mutect2, varscan2
- PPFIA3 | c.1104G>A p.A368= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV100495251; called by muse, mutect2, varscan2
- SALL1 | c.1314G>A p.A438= | Silent (SNP) | VAF 34/131 reads (26%) | catalogued as rs556441449, COSV51752735, COSV99171607; called by muse, mutect2, varscan2
- SETDB1 | c.63G>A p.E21= | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as rs1169130646, COSV99645842; called by muse, mutect2, varscan2
- SHROOM3 | c.3885C>T p.L1295= | Silent (SNP) | VAF 42/178 reads (24%) | catalogued as COSV99935283; called by muse, mutect2, varscan2
- SIGLEC12 | c.1719G>A p.A573= (on ENST00000291707 / NM_053003.4; = p.A455= on NM_033329.2) | Silent (SNP) | VAF 18/192 reads (9%) | catalogued as rs1386183006, COSV99389587; called by muse, mutect2
- SKI | c.708C>T p.L236= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs747283757, COSV101049616, COSV66013418; called by muse, mutect2, varscan2
- SLC19A1 | c.171G>A p.K57= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs765827796, COSV100229106; called by muse, varscan2
- SLC6A20 | c.1308G>C p.L436= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as rs748133403, COSV100653972; called by muse, mutect2, varscan2
- SLC7A6OS | c.412T>C p.L138= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV99862381; called by muse, mutect2, varscan2
- SPATA31A1 | c.1359C>G p.V453= | Silent (SNP) | VAF 88/422 reads (21%) | called by muse, mutect2, varscan2
- SPIB | c.78G>A p.L26= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs775746202, COSV99570142; called by muse, mutect2, varscan2
- SUN5 | c.108G>A p.R36= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV50064844, COSV99401660; called by muse, mutect2, varscan2
- TAS2R31 | c.891G>C p.V297= | Silent (SNP) | VAF 51/309 reads (17%) | catalogued as COSV101115565; called by muse, varscan2
- TENT5B | c.837C>T p.L279= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs1355709393, COSV100006741; called by muse, mutect2, varscan2
- TMEM266 | c.747G>A p.T249= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs775930403, COSV66378514; called by muse, mutect2, varscan2
- TTBK1 | c.27G>A p.K9= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs751441680, COSV52497963; called by muse, mutect2, varscan2
- UNC13B | c.4350C>T p.L1450= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as COSV100266879; called by muse, mutect2, varscan2
- VPS13A | c.3585T>G p.T1195= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV100653474, COSV62432755; called by muse, mutect2, varscan2
- WAS | c.78C>G p.L26= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV100939533; called by muse, mutect2, varscan2
- WHRN | c.144G>A p.A48= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV99470574; called by muse, mutect2
- YME1L1 | c.762C>T p.L254= (on ENST00000326799 / NM_139312.3; = p.L197= on NM_014263.4) | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV100464145; called by muse, mutect2, varscan2
- ZNF513 | c.663G>A p.L221= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV99277934; called by muse, mutect2, varscan2
- ZNF615 | c.807C>T p.F269= | Silent (SNP) | VAF 24/252 reads (10%) | catalogued as rs764738499, COSV100943960; called by muse, mutect2
- ZNF765 | c.1473G>A p.Q491= | Silent (SNP) | VAF 14/112 reads (13%) | catalogued as COSV101125568; called by muse, mutect2, varscan2
- ZNF98 | c.648G>A p.G216= | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- ALAD | c.114-155G>A | Intron (SNP) | VAF 5/32 reads (16%) | catalogued as rs772806904, COSV99475028; called by muse, mutect2
- BCAS1 | c.927+2420A>T | Intron (SNP) | VAF 8/45 reads (18%) | catalogued as COSV101006432; called by muse, mutect2, varscan2
- CTAG2 | c.*130G>A | 3'UTR (SNP) | VAF 22/81 reads (27%) | catalogued as COSV99909185; called by muse, mutect2, varscan2
- OBSCN | c.5138-1677C>T | Intron (SNP) | VAF 14/86 reads (16%) | catalogued as COSV99483989; called by muse, mutect2, varscan2
- TTN | c.10360+1409C>T | Intron (SNP) | VAF 43/146 reads (29%) | catalogued as COSV100628799; called by muse, mutect2, varscan2
